Somatic mutation profile of tumor specimen TCGA-HT-A4DS-01A (aliquot TCGA-HT-A4DS-01A-11D-A26M-08) from TCGA case TCGA-HT-A4DS, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 55.6 years (20,296 days).
Specimen TCGA-HT-A4DS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10a5ef1f-6f2e-41f5-9d97-1b755b038b7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A4DS-10A (Blood Derived Normal), aliquot TCGA-HT-A4DS-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb6d92fc-c38a-4627-91ce-41cc8147563e

The open-access MAF lists 32 somatic variants for this specimen: 28 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 26, Silent 4, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 6/9 reads (67%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1381311657, COSV56980020; called by muse, mutect2, varscan2
- BPIFB4 | c.1813G>A p.V605M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as rs138732736; called by muse, mutect2, varscan2
- DYNC1H1 | c.5864G>T p.G1955V | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64139769, COSV64141635; called by muse, mutect2, varscan2
- GABRA6 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200373173, COSV50877577, COSV50900675; called by muse, mutect2, varscan2
- HIRIP3 | c.259A>G p.S87G | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV54231565; called by muse, mutect2
- IPO9 | c.883T>C p.W295R | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64235625; called by muse, mutect2, varscan2
- LRRC32 | c.1009C>A p.H337N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.085); catalogued as COSV52635149; called by muse, mutect2, varscan2
- LRRC59 | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 89/138 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); catalogued as rs140038553; called by muse, mutect2, varscan2
- LTA4H | c.877G>C p.V293L | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57384216; called by muse, mutect2, varscan2
- MUC7 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.009); catalogued as rs145866670; called by muse, mutect2, varscan2
- NF1 | c.1019_1020del p.S340Cfs*12 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | catalogued as rs1555610903; called by pindel, varscan2
- OR2V2 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV60316334; called by muse, mutect2, varscan2
- OTUD7A | c.1919G>A p.R640H (on ENST00000307050 / NM_001382637.1; = p.R633H on NM_130901.3) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61042816; called by muse, mutect2, varscan2
- PCDHA1 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.95); catalogued as rs782375835, COSV65373488; called by muse, mutect2, varscan2
- PCDHAC2 | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53866293; called by muse, mutect2
- PCNX1 | c.1637C>T p.S546F | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV53098172, COSV53100738; called by muse, mutect2, varscan2
- PKD1L1 | c.7493C>T p.T2498M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.667); catalogued as rs367611487; called by muse, mutect2
- RERE | c.4698A>C p.L1566F | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV61949320; called by muse, mutect2, varscan2
- RUNX3 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs926240296, COSV58245639; called by muse, mutect2, varscan2
- SAG | c.510G>C p.K170N | Missense Mutation (SNP) | VAF 78/133 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV68590976, COSV68592231; called by muse, mutect2, varscan2
- SLC6A19 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs770356208, COSV58671837; called by muse, mutect2, varscan2
- SOX4 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV55193897; called by mutect2, varscan2
- SPNS3 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs760499890, COSV61069133; called by muse, mutect2, varscan2
- ST8SIA5 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | PolyPhen probably damaging (1); catalogued as rs1007101887, COSV59334634; called by muse, mutect2, varscan2
- TDG | c.478+1G>T p.X160_splice | Splice Site (SNP) | VAF 36/49 reads (73%) | catalogued as COSV57168306; called by muse, mutect2, varscan2
- TTLL3 | c.1801G>A p.V601M | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT tolerated (0.64); PolyPhen benign (0.073); catalogued as rs771480120, COSV59613675; called by muse, mutect2, varscan2
- ZNF654 | c.2735T>C p.V912A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV58807109; called by muse, mutect2, varscan2
- EPHA8 | c.2055G>A p.A685= | Silent (SNP) | VAF 81/147 reads (55%) | catalogued as rs201370742, COSV51266564; called by muse, mutect2, varscan2
- FRAS1 | c.7080C>T p.I2360= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as rs770304597, COSV53612737; called by muse, mutect2, varscan2
- MICB | c.144G>A p.E48= | Silent (SNP) | VAF 29/51 reads (57%) | catalogued as COSV52857722; called by muse, mutect2, varscan2
- ZNF536 | c.3738G>A p.A1246= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs763122092, COSV62817654; called by muse, mutect2, varscan2
